Somatic mutation profile of tumor specimen e515eb5c-8005-416a-9b42-59de9d (aliquot e515eb5c-8005-416a-9b42-59de9d_D6_1) from CPTAC case 11CO057, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen e515eb5c-8005-416a-9b42-59de9d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b126e354-59e5-498e-b98a-6b632575c16c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 428d09b8-eca7-432f-8af9-6b5697 (Blood Derived Normal), aliquot 428d09b8-eca7-432f-8af9-6b5697_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9303718a-0624-49ea-a881-9623e05fd05b

The open-access MAF lists 153 somatic variants for this specimen: 94 protein-altering or splice-affecting, 39 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 39, Intron 13, Nonsense Mutation 9, Splice Region 3, 3'UTR 2, Frame Shift Del 2, RNA 2, 5'Flank 2, Frame Shift Ins 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 145/291 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 92/304 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 72/293 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: likely pathogenic; called by muse, varscan2
- ABCA3 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 25/417 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183645105; ClinVar: uncertain significance; called by muse, mutect2
- AP3B1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs758616866; called by muse, varscan2
- APC | c.4455del p.D1486Ifs*21 | Frame Shift Del (DEL) | VAF 41/103 reads (40%) | catalogued as COSV57321956; called by mutect2, pindel, varscan2
- ARIH1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs770559164, COSV101158779; called by muse, mutect2, varscan2
- BRSK1 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1179003070; called by muse, mutect2, varscan2
- C4A | c.3214C>T p.R1072W | Missense Mutation (SNP) | VAF 253/1410 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs201134904, COSV71177662; called by muse, mutect2, varscan2
- CACNB2 | c.1312G>A p.D438N (on ENST00000324631 / NM_201596.3; = p.D383N on NM_000724.4) | Missense Mutation (SNP) | VAF 87/319 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778466195, COSV56612862; called by muse, mutect2, varscan2
- CAMTA1 | c.4853G>A p.R1618Q | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs779607705; called by muse, mutect2, varscan2
- CCDC27 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 170/332 reads (51%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1037393854, COSV53898617; called by muse, mutect2, varscan2
- CDCA8 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 84/135 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557519027; called by muse, mutect2, varscan2
- CSMD3 | c.5919G>C p.E1973D (on ENST00000297405 / NM_001363185.1; = p.E1869D on NM_052900.3) | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs766489936, COSV52219235; called by muse, mutect2, varscan2
- DMRT3 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs375503288; called by muse, mutect2, varscan2
- DNAAF3 | c.658C>T p.R220C (on ENST00000524407 / NM_001256715.2; = p.R267C on NM_178837.4) | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV61276695; called by muse, mutect2, varscan2
- EPHA8 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as rs138090615; called by muse, mutect2, varscan2
- ERVW-1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); catalogued as rs538492656; called by muse, mutect2, varscan2
- FAM205A | c.3946C>T p.R1316C | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.537); catalogued as rs1025907802, COSV66488778; called by muse, mutect2, varscan2
- FAT3 | c.2915G>A p.R972H | Missense Mutation (SNP) | VAF 97/359 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1382417399, COSV53073195; called by muse, mutect2, varscan2
- GALNTL6 | c.1720G>T p.D574Y | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV72490060, COSV72491800; called by muse, varscan2
- GOLGB1 | c.7889A>G p.Y2630C | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs769861496; called by muse, mutect2, varscan2
- GPR174 | c.322T>G p.F108V | Missense Mutation (SNP) | VAF 80/405 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52132271; called by muse, mutect2, varscan2
- GTF2F1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 138/308 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs368947114; called by muse, mutect2, varscan2
- HCAR1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs201961889; called by muse, mutect2, varscan2
- HPS3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202087344; called by muse, mutect2, varscan2
- IGF2BP3 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51693646; called by muse, mutect2, varscan2
- IRF7 | c.282dup p.E95Rfs*3 (on ENST00000397566; = p.E82Rfs*3 on NM_001572.5) | Frame Shift Ins (INS) | VAF 29/95 reads (31%) | catalogued as rs757899679; called by mutect2, pindel, varscan2
- ITGA7 | c.3332G>A p.R1111Q (on ENST00000555728; = p.R1067Q on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/427 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs752159189, COSV57696263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KAT2A | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1555666192, COSV99288255; called by muse, mutect2, varscan2
- KCNH7 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV100038486; called by muse, mutect2
- LRRK2 | c.7168G>A p.V2390M | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs79546190, CM081328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MACF1 | c.14803C>G p.R4935G (on ENST00000372915; = p.R2868G on NM_012090.5) | Missense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as COSV57141578; called by muse, mutect2, varscan2
- MAT2B | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766882760; called by muse, varscan2
- MED1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs768496336, COSV100327964; called by muse, mutect2, varscan2
- MGA | c.2207C>A p.S736* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV99581494; called by muse, mutect2, varscan2
- MGAT4C | c.698T>A p.F233Y | Missense Mutation (SNP) | VAF 123/266 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100152508, COSV59833834; called by muse, mutect2, varscan2
- NOTCH1 | c.5348G>A p.R1783Q | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV53041984; called by muse, mutect2, varscan2
- PARP6 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.889); catalogued as rs1488770227, COSV99536082; called by muse, mutect2, varscan2
- PKHD1L1 | c.8515G>C p.D2839H | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as rs755076910; called by muse, mutect2, varscan2
- PLEKHG4B | c.2936G>A p.R979H (on ENST00000283426; = p.R1335H on NM_052909.5) | Missense Mutation (SNP) | VAF 88/306 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774446632, COSV52054815; called by muse, mutect2, varscan2
- PRB1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs1280147632; called by muse, mutect2, varscan2
- PRRT4 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as rs1004889437; called by muse, mutect2, varscan2
- PTGIR | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1425817585, COSV52191744; called by muse, varscan2
- PTPRC | c.2346G>C p.K782N | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs771626124, COSV61407331; called by muse, mutect2, varscan2
- SHOX | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 37/472 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.613); catalogued as rs751167018, COSV61861680, COSV61862648; called by muse, mutect2
- SIN3A | c.2620C>T p.Q874* | Nonsense Mutation (SNP) | VAF 71/268 reads (26%) | catalogued as COSV100845202; called by muse, mutect2, varscan2
- SLC16A2 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 26/391 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as rs1375705723; called by muse, mutect2
- SPINK5 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 25/171 reads (15%) | catalogued as COSV56258034; called by muse, mutect2, varscan2
- STAC | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1353001900; called by muse, mutect2
- STMND1 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 30/116 reads (26%) | catalogued as rs535932632; called by muse, mutect2, varscan2
- SYNJ2 | c.3668C>T p.A1223V | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs766478029; called by muse, mutect2, varscan2
- TET1 | c.5338C>T p.R1780* | Nonsense Mutation (SNP) | VAF 46/134 reads (34%) | catalogued as COSV65383466; called by muse, mutect2, varscan2
- TGM2 | c.55C>T p.R19* | Nonsense Mutation (SNP) | VAF 218/684 reads (32%) | catalogued as rs780078049; called by muse, varscan2
- TTN | c.58703G>A p.R19568Q (on ENST00000591111; = p.R12144Q on NM_003319.4) | Missense Mutation (SNP) | VAF 15/126 reads (12%) | PolyPhen benign (0.396); catalogued as rs148684589; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- XPNPEP2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778659869, COSV64367754; called by muse, mutect2, varscan2
- ZNF615 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 53/398 reads (13%) | catalogued as rs751049058; called by muse, mutect2, varscan2
- ZNF716 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782278077, COSV70782673; called by muse, mutect2
- ALG6 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ARMCX5 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 161/214 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATN1 | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BBS5 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCNE1 | c.824T>G p.F275C | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHD4 | c.3405G>C p.W1135C (on ENST00000357008 / NM_001363606.2; = p.W1148C on NM_001273.5) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYSLTR1 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 101/140 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- DOP1B | c.670C>G p.H224D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DPYSL3 | c.148_151del p.I50Ffs*5 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | called by mutect2, pindel, varscan2
- EYA4 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 119/640 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- GPT | c.838T>G p.Y280D | Missense Mutation (SNP) | VAF 141/739 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGF2R | c.3614G>T p.C1205F | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRX1 | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.154); called by mutect2, varscan2
- LCA5L | c.463A>G p.K155E | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRK2 | c.7391-3A>G | Splice Region (SNP) | VAF 27/129 reads (21%) | called by muse, mutect2, varscan2
- MAPK3 | c.482A>C p.N161T | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MEP1A | c.265C>T p.L89= | Splice Region (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- MYO10 | c.2648A>G p.E883G | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- OTUB1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- P2RX4 | c.1047G>A p.A349= | Splice Region (SNP) | VAF 54/145 reads (37%) | called by muse, mutect2, varscan2
- PABPC5 | c.195C>A p.N65K | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE4D | c.1347G>T p.M449I (on ENST00000340635 / NM_001104631.2; = p.M313I on NM_006203.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PRDM8 | c.1961T>G p.M654R | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- PRKCA | c.1605+1G>A p.X535_splice | Splice Site (SNP) | VAF 56/180 reads (31%) | called by muse, mutect2, varscan2
- PRSS58 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.136); called by muse, mutect2
- PSTPIP1 | c.977C>G p.A326G | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RBMS3 | c.1019T>C p.M340T | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ROCK2 | c.3341G>A p.S1114N | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SALL1 | c.3626A>T p.N1209I | Missense Mutation (SNP) | VAF 105/316 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- STK35 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- TACR1 | c.522G>A p.M174I | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMPRSS11D | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- TRPS1 | c.3843G>C p.E1281D (on ENST00000220888 / NM_001330599.2; = p.E1294D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- XKR3 | c.806T>A p.L269* | Nonsense Mutation (SNP) | VAF 66/249 reads (27%) | called by muse, mutect2, varscan2
- ZNF138 | c.361C>A p.Q121K (on ENST00000307355 / NM_001367572.1; = p.Q95K on NM_006524.4) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACOX3 | c.1275G>A p.A425= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as rs753101879, COSV62711039; called by muse, mutect2, varscan2
- ALG2 | c.1083G>T p.L361= | Silent (SNP) | VAF 60/201 reads (30%) | called by muse, mutect2, varscan2
- ATP1A3 | c.1839C>A p.G613= (on ENST00000545399 / NM_001256214.2; = p.G600= on NM_152296.5) | Silent (SNP) | VAF 40/662 reads (6%) | called by muse, mutect2
- B3GALT6 | c.738C>T p.G246= | Silent (SNP) | VAF 141/225 reads (63%) | catalogued as COSV99767692; called by muse, mutect2, varscan2
- CCDC197 | c.129C>T p.V43= | Silent (SNP) | VAF 82/142 reads (58%) | catalogued as rs906774023; called by muse, mutect2, varscan2
- CLUH | c.1344G>A p.A448= (on ENST00000435359; = p.A486= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/263 reads (15%) | catalogued as rs776067502, COSV70927646; called by muse, mutect2, varscan2
- CNTFR | c.261C>T p.Y87= | Silent (SNP) | VAF 136/489 reads (28%) | catalogued as rs763761871; called by muse, mutect2, varscan2
- DCAF4L2 | c.363C>T p.Y121= | Silent (SNP) | VAF 289/841 reads (34%) | catalogued as rs752826822, COSV60480690; called by muse, mutect2, varscan2
- FAT4 | c.8406C>T p.D2802= | Silent (SNP) | VAF 22/210 reads (10%) | called by muse, mutect2
- GTF3C1 | c.6078G>A p.Q2026= | Silent (SNP) | VAF 88/245 reads (36%) | catalogued as rs940833633; called by muse, mutect2, varscan2
- HINFP | c.459C>T p.H153= | Silent (SNP) | VAF 49/171 reads (29%) | called by muse, mutect2, varscan2
- HTR1E | c.621C>T p.H207= | Silent (SNP) | VAF 90/352 reads (26%) | catalogued as rs377350581; called by muse, mutect2, varscan2
- ILDR2 | c.900C>T p.I300= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as rs1156821266; called by muse, mutect2, varscan2
- KALRN | c.7413A>T p.P2471= (on ENST00000360013 / NM_001024660.4; = p.P774= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- KCNV2 | c.867G>T p.S289= | Silent (SNP) | VAF 300/982 reads (31%) | catalogued as rs765405789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL1 | c.867G>A p.A289= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as rs772429365, COSV64775590; called by muse, mutect2, varscan2
- MAMLD1 | c.414C>T p.G138= | Silent (SNP) | VAF 50/372 reads (13%) | catalogued as COSV53380043; called by muse, mutect2, varscan2
- NACA2 | c.540C>T p.D180= | Silent (SNP) | VAF 76/294 reads (26%) | catalogued as rs149192515; called by muse, mutect2, varscan2
- NEXMIF | c.3639C>A p.G1213= | Silent (SNP) | VAF 92/238 reads (39%) | called by muse, mutect2, varscan2
- OBSCN | c.4656C>A p.A1552= | Silent (SNP) | VAF 73/480 reads (15%) | catalogued as COSV99481798; called by muse, mutect2, varscan2
- OPRL1 | c.876G>A p.P292= | Silent (SNP) | VAF 85/492 reads (17%) | catalogued as rs141090449; called by muse, mutect2, varscan2
- OR10G3 | c.462C>A p.S154= | Silent (SNP) | VAF 192/293 reads (66%) | catalogued as COSV57811218; called by muse, mutect2, varscan2
- P2RY8 | c.483C>T p.T161= | Silent (SNP) | VAF 183/485 reads (38%) | catalogued as rs748140566, COSV67178190; called by muse, mutect2, varscan2
- PACS1 | c.2514C>T p.G838= | Silent (SNP) | VAF 66/235 reads (28%) | catalogued as rs199684328; called by muse, mutect2, varscan2
- PCDHA12 | c.2073G>A p.A691= | Silent (SNP) | VAF 254/726 reads (35%) | catalogued as COSV56485969; called by muse, mutect2, varscan2
- PCDHGA2 | c.1722C>T p.G574= | Silent (SNP) | VAF 205/790 reads (26%) | catalogued as COSV53912616; called by muse, mutect2, varscan2
- PKD1 | c.10380G>A p.S3460= (on ENST00000262304 / NM_001009944.3; = p.S3459= on NM_000296.4) | Silent (SNP) | VAF 182/558 reads (33%) | catalogued as rs369298152; called by muse, mutect2, varscan2
- PKD1L3 | c.3129C>T p.L1043= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs545366386; called by muse, mutect2, varscan2
- PTPRN2 | c.2466G>A p.P822= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs756403590, COSV67045606; called by muse, mutect2, varscan2
- RIOX1 | c.1416G>A p.P472= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as rs1307396636, COSV58374424; called by muse, mutect2, varscan2
- RTN4RL1 | c.255G>A p.S85= | Silent (SNP) | VAF 74/246 reads (30%) | catalogued as rs748945432, COSV58675476; called by muse, mutect2, varscan2
- SEMA4F | c.441G>A p.P147= | Silent (SNP) | VAF 112/294 reads (38%) | catalogued as rs763353637; called by muse, mutect2, varscan2
- SLC27A5 | c.813G>A p.A271= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as rs559467414, COSV54021846; called by mutect2, varscan2
- SLC46A2 | c.450C>T p.S150= | Silent (SNP) | VAF 114/364 reads (31%) | catalogued as rs1300430475; called by muse, mutect2, varscan2
- SLIT3 | c.657C>T p.C219= | Silent (SNP) | VAF 62/204 reads (30%) | catalogued as rs200407914, COSV60591736, COSV60630156; called by muse, mutect2, varscan2
- TENM2 | c.4377T>C p.P1459= (on ENST00000518659 / NM_001122679.2; = p.P1220= on NM_001080428.3) | Silent (SNP) | VAF 79/276 reads (29%) | called by muse, mutect2, varscan2
- ZFAT | c.2307G>A p.L769= | Silent (SNP) | VAF 64/182 reads (35%) | called by muse, mutect2, varscan2
- ZNF512B | c.1404C>T p.D468= | Silent (SNP) | VAF 20/300 reads (7%) | catalogued as rs148117690; called by muse, mutect2
- ZNF799 | c.1497A>G p.T499= | Silent (SNP) | VAF 124/317 reads (39%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.435G>T | RNA (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- ARMH3 | c.414+174A>G | Intron (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- ATL3 | chr11:63671431 G>A | 5'Flank (SNP) | VAF 12/34 reads (35%) | catalogued as rs546581078; called by muse, varscan2
- C1orf105 | c.199-3310A>G | Intron (SNP) | VAF 20/188 reads (11%) | catalogued as rs1409005712; called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-121-25644C>T | Intron (SNP) | VAF 24/137 reads (18%) | catalogued as rs1183207873, COSV66969190; called by muse, mutect2, varscan2
- CARD9 | c.1269+81C>T | Intron (SNP) | VAF 51/176 reads (29%) | called by muse, mutect2, varscan2
- GULP1 | c.843+103G>A | Intron (SNP) | VAF 53/154 reads (34%) | catalogued as rs751519015, COSV100771082; called by muse, mutect2, varscan2
- ITPR1 | c.5197-19T>C | Intron (SNP) | VAF 32/132 reads (24%) | called by muse, mutect2, varscan2
- NXF1 | c.29-134G>A | Intron (SNP) | VAF 37/119 reads (31%) | catalogued as rs976525391; called by muse, mutect2, varscan2
- RAPGEF3 | c.2374-57G>C | Intron (SNP) | VAF 69/159 reads (43%) | called by muse, mutect2, varscan2
- RIC3 | c.522-1470C>T | Intron (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- SAMSN1 | c.-25C>T | 5'UTR (SNP) | VAF 19/88 reads (22%) | catalogued as rs1346565648; called by muse, mutect2, varscan2
- SPATA31C1 | n.1720C>A | RNA (SNP) | VAF 70/557 reads (13%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133568138 G>A | 5'Flank (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2
- TINF2 | c.1222-19C>T | Intron (SNP) | VAF 182/608 reads (30%) | called by muse, mutect2, varscan2
- UMPS | c.*2158T>C | 3'UTR (SNP) | VAF 105/379 reads (28%) | called by muse, mutect2, varscan2
- UTY | c.645+21A>G | Intron (SNP) | VAF 36/47 reads (77%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+83T>G | Intron (SNP) | VAF 21/84 reads (25%) | called by mutect2, varscan2
- WDR1 | c.559-4332C>A | Intron (SNP) | VAF 64/290 reads (22%) | called by muse, mutect2, varscan2
- ZNF99 | c.*3074C>T | 3'UTR (SNP) | VAF 16/57 reads (28%) | catalogued as rs376716173, COSV68055649; called by muse, mutect2, varscan2
